Somatic mutation profile of tumor specimen 0DCYOM from CCDI case PBBMJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 3.0 years (1,081 days).
Specimen 0DCYOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 059a93e1-cb77-44ba-8dc0-a3492a992607.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCYOB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67fc782c-e115-495e-8c23-c6112da13d9b

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIRE | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs552129156, COSV52393851, COSV52397149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SSTR5 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs752514090, COSV53511309; called by muse, mutect2, varscan2
- BCOR | c.3339C>T p.S1113= | Silent (SNP) | VAF 211/242 reads (87%) | catalogued as rs1226506629, COSV60719608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
